Gene-level copy-number profile of tumor specimen ALCH-B426-TTP1-A from ALCHEMIST case ALCH-B426, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.9 years (21,868 days).
Specimen ALCH-B426-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a70dabf-6b0b-4ee7-9684-c818810c3e1e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B426-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/3f7cb348-522e-4c25-8c2d-cfff683d9c67

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 2,252; copy number 2: 55,951; copy number 3: 93; copy number 4: 8; copy number 5: 15; copy number 6: 4; copy number 7: 5; copy number 11: 2; copy number 12: 4; copy number 13: 1; copy number 18: 2; copy number 19: 1; copy number 25: 1; copy number 40: 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,398,592–10,420,511, 1 gene: PGD.
- chr1:26,169,516–26,171,831, 2 genes: AL391650.1, ZNF593.
- chr1:28,505,943–28,539,300, 1 gene (within-gene range 0–2): RCC1.
- chr1:28,526,318–28,527,227, 1 gene: PRDX3P2.
- chr1:47,438,044–47,440,691, 1 gene: FOXD2.
- chr2:230,864,639–230,904,693, 2 genes: ITM2C, GCSIR.
- chr3:129,528,639–129,551,467, 2 genes: RHO, H1-8.
- chr11:298,200–333,688, 12 genes: IFITM5, AC136475.6, IFITM2, AC136475.2, IFITM1, AC136475.1, IFITM3, AC136475.4, AC136475.8, AC136475.7, AC136475.5, AC136475.9.
- chr11:117,178,736–117,197,445, 1 gene: SIDT2.
- chr12:109,573,255–109,598,125, 1 gene (within-gene range 0–2): MVK.
- chr13:21,319,156–21,320,866, 1 gene (within-gene range 0–2): GRK6P1.
- chr14:23,415,339–23,415,686, 1 gene (within-gene range 0–2): AL132855.1.
- chr14:105,248,490–105,251,093, 1 gene (within-gene range 0–1): BTBD6.
- chr15:40,844,018–40,910,337, 5 genes (within-gene range 0–2): SPINT1, RHOV, AC025166.1, VPS18, AC020661.1.
- chr15:41,828,092–41,848,155, 3 genes (within-gene range 0–2): JMJD7, JMJD7-PLA2G4B, PLA2G4B.
- chr15:41,851,913–41,852,029, 1 gene (within-gene range 0–2): RNA5SP393.
- chr15:73,335,260–73,342,387, 1 gene (within-gene range 0–2): AC068397.2.
- chr15:85,744,109–85,794,925, 6 genes (within-gene range 0–2): AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr17:44,924,709–44,948,939, 3 genes: KIF18B, MIR6783, AC015936.1.
- chr17:44,959,693–44,968,303, 1 gene: C1QL1.
- chr19:8,520,778–8,610,735, 4 genes: MYO1F, AC092316.1, ADAMTS10, AC130469.1.
- chr19:39,196,964–39,204,263, 2 genes: NCCRP1, SYCN.
- chr19:48,630,030–48,637,379, 1 gene (within-gene range 0–2): DBP.
- chr22:37,065,436–37,109,713, 2 genes: TMPRSS6, AL022314.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 36 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,169,087, 4 genes, copy number 6–13: LINC01342, MIR200B, MIR200A, MIR429.
- chr8:143,412,749–143,430,732, 3 genes, copy number 5: AC105118.1, MAFA-AS1, MAFA.
- chr11:112,967–139,612, 3 genes, copy number 7–18 (within-gene range 2–18): AC069287.1, CICP23, LINC01001.
- chr11:278,407–296,107, 3 genes, copy number 7: NLRP6, AC136475.3, PGGHG.
- chr11:777,578–809,753, 7 genes, copy number 5 (within-gene range 4–5): AP006621.3, AP006621.5, AP006621.2, CEND1, SLC25A22, AP006621.6, PIDD1.
- chr11:832,887–842,529, 2 genes, copy number 5: CD151, POLR2L.
- chr11:1,947,278–1,989,920, 2 genes, copy number 6–40: MRPL23, MRPL23-AS1.
- chr14:105,583,731–105,626,066, 4 genes, copy number 5–19: IGHA2, IGHE, IGHG4, MIR8071-1.
- chr16:678,504–684,528, 4 genes, copy number 12 (within-gene range 2–12): LINC02867, Z92544.2, STUB1, JMJD8.
- chr19:2,328,615–2,355,095, 1 gene, copy number 5 (within-gene range 2–5): SPPL2B.
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 25 (within-gene range 4–25): LINC00313.
- chr21:44,133,610–44,210,114, 1 gene, copy number 11 (within-gene range 2–11): GATD3A.

Autosomal genes at a single copy (total copy number 1): 2,046. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
